TARGET case TARGET-40-NAAFJR — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1b1209f2-7d26-54a0-9e6e-0d14afb6e0d2

Demographics
Sex at birth: male; Race: american indian or alaska native; Ethnicity: not hispanic or latino; Age at index: 18 years; Vital status: Dead; Days to death: 606 days (1.7 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 19.0 years (6,931 days); Year of diagnosis: 2003; Metastasis at diagnosis: No Metastasis; Days to last follow up: 606 days (1.7 years).
   Pathology details: Necrosis percent: 50.
   Treatment given: Protocol identifier: IHRT.
   Treatment given: Therapeutic agents: Cisplatin.
   Treatment given: Therapeutic agents: Doxorubicin.
   Treatment given: Therapeutic agents: Methotrexate.

Follow-up (2 entries)
- Days to follow up: 380 days (1.0 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 380 days (1.0 years); Days to first event: 380 days (1.0 years); First event: Relapse.
- Days to follow up: 606 days (1.7 years); Year of follow up: 2005.

Biospecimens (1 sample)
- Sample TARGET-40-NAAFJR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAFJR-01A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 98
- % Non Tumor Nuclei: Top from Biopsy: 2
- % Cellular Tumor: Top from Biopsy: 90
- % Normal: Top from Biopsy: 0
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 10
- % Tumor Nuclei: Bottom from Biopsy: 95
- % Non Tumor Nuclei: Bottom from Biopsy: 5
- % Cellular Tumor: Bottom from Biopsy: 50
- % Normal: Bottom from Biopsy: 40
- % Stroma: Bottom from Biopsy: 10
- % Necrosis: Bottom from Biopsy: 0
- PASS/FAIL: pass

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 606
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Specific tumor region: Distal
- Definitive Surgery: Amputation
- Primary site progression: No
- Site of initial relapse: Other bone
- Histologic response: Stage 1/2 (0-90 % necrosis)
- Relapse Type: Systemic- Other Bone- spine & chest wall
- Therapy: MTX, Adria, Cis
